Gene-level copy-number profile of tumor specimen TCGA-2G-AAHT-01A from TCGA case TCGA-2G-AAHT, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 32.6 years (11,905 days).
Specimen TCGA-2G-AAHT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-TGCT.78d1c049-6e91-4be2-9686-3aacbb995d8c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2G-AAHT-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5874e54c-bc0c-49c7-b21f-ee7994cdf963

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,571; copy number 2: 16,398; copy number 3: 27,284; copy number 4: 12,746; copy number 5: 796; copy number 6: 863; copy number 7: 118; copy number 11: 35.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2G-AAHT-01A-11D-A42X-01): tumor purity 0.52, ploidy 3, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 153 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:53,377,839–54,295,272, 1 gene, copy number 7 (within-gene range 2–7): AC058822.1.
- chr4:53,899,871–65,860,204, 152 genes, copy number 7–11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 526. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
